Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53B, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53B-01A (Primary Tumor).

[page 1 of 4]
1C5-0-3

Carcinoma, Squamous cell, NOS 807013

Site: Lung, Upper lobe C34.1

hw 11/25/12

Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

- A. Lymph node, level IX, excision: - One lymph node negative for malignancy (0/1).
- B. Lymph node, level VIII, excision: - One lymph node negative for malignancy (0/1).
- C. Lymph node, level IX, excision: - Two lymph nodes negative for malignancy (0/2).
- D. Lymph node, level VII, excision: - One lymph node negative for malignancy (0/1).
- E. Lymph node, level V, excision: - One lymph node negative for malignancy (0/1).
- F. Lymph node, level V, excision: - One lymph node negative for malignancy (0/1).
- G. Lymph node, level IV-L, excision: - One lymph node negative for malignancy (0/1).
- H. Lymph node, level X, excision: - One lymph node negative for malignancy (0/1).
- I. Lymph node, level XI, excision: - One lymph node negative for malignancy (0/1).
- J. Lymph node, level VI, excision: - One lymph node negative for malignancy (0/1).
- K. Lymph node, level XII, excision: - One lymph node negative for malignancy (0/1).
- L. Lymph node, level X, excision: - One lymph node negative for malignancy (0/1).
- M. Lymph node, level XIII, excision: - One lymph node negative for malignancy (0/1).
- N. Lymph node, level XII, excision: - One lymph node negative for malignancy (0/1).
- O. Lung, left upper lobe, bronchial margin, excision: - Negative for malignancy.
- P. Lung, left upper lobe, lobectomy: - Squamous cell carcinoma, moderately differentiated, 4 cm in maximum dimension. - Carcinoma abuts, but does not invade, the pleura. - Parenchymal margins negative for malignancy. - Two perihilar lymph nodes negative for malignancy (0/2). - Non neoplastic lung parenchyma shows marked interstitial fibrosis, scattered lymphoid aggregates, and mild medial hypertrophy of medium sized arteries (see comment). - pT2a N0 Mx.

Pathologist Comments

Clinical note states that an outside CT scan demonstrated chronic interstitial lung changes including bullae, cysts and honeycombing bilaterally. Sections of lung away from the tumor show significant interstitial fibrosis of uniform temporal pattern, scattered chronic inflammation, thickened arteries, and early honeycombing changes; no granulomas are seen.

Clinical Information

The patient is a year old male with lung cancer in the left upper lobe with some enlarged lymph nodes who is a current everyday smoker. The patient has coronary artery disease and interstitial lung disease.

Frozen Section Diagnosis

- B1: Lymph node, level VIII, biopsy: - No tumor seen.
- C1: Lymph node, level IX, biopsy: - No tumor seen.
- D1: Lymph node, level VII, biopsy: - No tumor seen.

[page 2 of 4]
E1: Lymph node, level V, biopsy: - No tumor seen.
F1: Lymph node, level V, biopsy: - No tumor seen.
G1: Lymph node, level IV-L, biopsy:- No tumor seen.
J1: Lymph node, level VI, biopsy: - No tumor seen.
O1: Lung, left upper lobe, bronchial margin, excision: - No tumor seen.
P1: Lung, left upper lobe, excision: - Squamous carcinoma.

Gross Description

The specimen is received in 15 containers, each labeled with the patient's name and medical record number. The first container is labeled, "#1, level IX lymph node." Received is an anthracotic tan-yellow fragment of tissue that measures 1.2 x 0.7 x 0.4 cm submitted in total.

The second container is labeled, "#2, level VIII lymph node." Received fresh for frozen section is an anthracotic lymph node that measures 1.2 x 0.8 x 0.5 cm submitted in total.

The next container is labeled, "#3, level IX lymph node." Received fresh for frozen section is an anthracotic fragment of tissue that measures 1.5 x 1.2 x 0.5 cm submitted in total for frozen.

The next container is labeled, "#4, level VII lymph node." Received fresh for frozen section is a single anthracotic fragment of tissue measuring 1.2 x 0.7 x 0.5 cm submitted in total for frozen.

The next container is labeled, "#5, level V lymph node." Received fresh for frozen section is a fragment of anthracotic tissue that measures 1.5 x 1.0 x 0.7 cm bisected and entirely submitted for frozen.

The next container is labeled, "#6, level V lymph node." Received is an anthracotic fragment of irregularly shaped tissue that measures 1.7 x 1.5 x 0.7 cm submitted in total for frozen.

The next container is labeled, "#7, level IV-L lymph node." Received fresh for frozen section is a single fragment of anthracotic irregularly shaped tissue measuring 2.0 x 1.7 x 0.5 cm submitted in total for frozen.

The next container is labeled, "#8, level X lymph node." Received is an anthracotic fragment of tissue that measures 0.4 x 0.3 x 0.3 cm submitted in total.

The next container is labeled, "#9, level XI lymph node." Received is a single anthracotic fragment of tissue that measures 0.6 x 0.4 x 0.3 cm submitted in total.

The next container is labeled, "#10, level VI lymph node." Received fresh for frozen section are irregularly shaped fragments of anthracotic tissue that measure in aggregate 2.9 x 2.8 x 0.7 cm entirely submitted.

The next container is labeled, "#11 level XII lymph node." Received are multiple anthracotic fragments of tissue that measure in aggregate 2.5 x 2.2 x 0.5 cm submitted in total.

The next container is labeled, "#12, level X lymph node." Received are two anthracotic fragments of tan-yellow tissue fragment measuring from 0.7 x 0.8 cm submitted in total.

The next container is labeled, "#13, level XIII lymph node." Received is an anthracotic fragment of tissue that measures 1.2 x 1.0 x 0.8 cm that is sectioned and entirely submitted.

The next container is labeled, "#14, level XII lymph node." Received is a single anthracotic fragment of tissue that measures 0.8 x 0.5 x 0.4 cm bisected and entirely submitted.

[page 3 of 4]
The next container is labeled, "#15, bronchial margin." Received fresh for frozen section is a linear fragment of cartilaginous mucosal lined tissue measuring 0.8 x 0.7 x 0.2 cm that is submitted in total for frozen.

The sixteenth container is additionally labeled, "#16, left upper lobe." Received is an orange cassette in formalin which was previously submitted fresh for frozen. It holds a piece of tan-brown anthracotic lung tissue measuring 2.5 x 1.8 x 0.3 cm. It is resubmitted entirely in cassette P1.

Also received in the sixteenth container is a lung lobe without fixative, measuring 20.0 x 10.0 x 4.5 cm. The visceral pleura is mottled tan/purple and anthracotic/black. There is a mass measuring 4.0 x 3.5 x 3.5 cm at the apex of the lobe. The mass was previously cut for frozen section, and also previously to that in the operating room after explant. The cut surface of tumor is tan and irregular, with solid and cystic areas. The cystic areas are traversed by bands of tumor tissue. The mass appears to abut, but not breach, the visceral pleura. Diffusely patchy areas surrounding the tumor are firmer to palpation than the grossly uninvolved lung parenchyma. The staple line of the medial parenchymal resection margin is removed and the cut surface inked black. The pleura over the tumor is inked blue. The tissue is then serially sectioned to reveal the following: The primary tumor is 1.8 cm away from the nearest surgical margin (medial parenchymal, black). It extends 3.0 cm deep into the lung tissue. It is well-circumscribed but not encapsulated, with an irregular deep contour. There is an area of grainy tan-green/black tissue 2.0 x 2.5 cm in maximum dimension lateral to the primary tumor. It too appears to touch but not breach the overlying pleura. It appears dissimilar to the primary tumor, but still pathological compared to the surrounding parenchyma. Similar foci of tan/green/black grainy tissue are scattered throughout the lung, mostly inferiorly. None form discrete masses. The uninvolved parenchyma is a heterogeneous beefy dark-red/anthracotic-black. One solid black perihilar lymph node is found. Representative sections are submitted per the block summary.

Block Summary

- A1- Level IX lymph node.
- B1- Level VIII lymph node.
- C1- Level IX lymph node.
- D1- Level VII lymph node.
- E1- Level V lymph node.
- F1- Level V lymph node.
- G1- Level IV-L lymph node.
- H1- Level X lymph node.
- I1- Level XI lymph node.
- J1- Level VI lymph node.
- K1- Level XII lymph nodes.
- L1- Level X lymph node.
- M1- Level XIII lymph node.
- N1- Level XII lymph node.
- O1- Bronchial margin.
- P1- Left upper lobe mass, frozen.
- P2-P3- Mass with respect to nearest surgical margin (black).
- P4-P6- Mass with respect to overlying pleura.
- P7-P8- Representative sections of tan/grainy area lateral to primary mass.
- P9- Representative section of inferior tan/grainy area, with both anterior and posterior pleura
- P10- Representative shave, medial parenchymal (black) margin.
- P11- Anthracotic hilar lymph node.
- P12-P13- Representative sections of grossly uninvolved lung.

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report P: Thorax Lung

SPECIMEN: Lobe(s) of lung: left upper lobe

[page 4 of 4]
PROCEDURE: Lobectomy
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Left
TUMOR SITE: Upper lobe
TUMOR SIZE: Greatest dimension: 4 cm
TUMOR FOCALITY: Unifocal
HISTOLOGIC TYPE: Squamous cell carcinoma
HISTOLOGIC GRADE: G2: Moderately differentiated
VISCERAL PLEURA INVASION: Not identified
TUMOR EXTENSION: Not identified
BRONCHIAL MARGIN: Uninvolved by invasive carcinoma
VASCULAR MARGIN: Uninvolved by invasive carcinoma
PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Not applicable
CHEST WALL MARGIN: Not applicable
OTHER ATTACHED TISSUE MARGIN: Not applicable
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Not identified
LYMPH NODES: Present

PRIMARY TUMOR (pT): pT2a: Tumor > 3 cm, and < 5 cm in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion in the main bronchus; or Tumor < 5 cm in greatest dimension with any of the following: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis
DISTANT METASTASIS (pM): Not applicable

Staging Discrepancy		✓
Metastatic History		✓
Second Synchronous Primary Tumor		✓
Case & Article	11/8/12	11/2/12

Source: NCI Genomic Data Commons file 3ce4a94a-aaf6-464f-86ff-327240c8c010 (TCGA-98-A53B.2BA70162-293A-4E9C-959C-0A735F18EA54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).